Somatic mutation profile of tumor specimen TCGA-ZJ-AAXU-01A (aliquot TCGA-ZJ-AAXU-01A-11D-A42O-09) from TCGA case TCGA-ZJ-AAXU, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 51.4 years (18,773 days).
Specimen TCGA-ZJ-AAXU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fb69d60-c8ee-458a-b0ad-b89217898bfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-AAXU-10A (Blood Derived Normal), aliquot TCGA-ZJ-AAXU-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7adecc8d-f2d6-44f7-944a-2f0db11efa01

The open-access MAF lists 437 somatic variants for this specimen: 316 protein-altering or splice-affecting, 114 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 269, Silent 114, Nonsense Mutation 36, Intron 5, Splice Site 4, Splice Region 4, 3'UTR 1, Frame Shift Del 1, In Frame Del 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 30/110 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- A4GNT | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99367819; called by muse, mutect2, varscan2
- AASDH | c.2728C>T p.H910Y | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as COSV99221186; called by muse, mutect2, varscan2
- ABCB1 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV55964105, COSV99712849; called by muse, mutect2, varscan2
- ACOXL | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV100490100, COSV61326050; called by muse, mutect2, varscan2
- ADCY5 | c.2432C>G p.S811C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV100567621; called by mutect2, varscan2
- ADGRD1 | c.1145-1G>C p.X382_splice | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99895163; called by muse, mutect2, varscan2
- ADGRL2 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV54658658; called by muse, mutect2, varscan2
- AFDN | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs931063190, COSV60048306; called by muse, mutect2, varscan2
- AFF2 | c.2147C>G p.S716C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782151497, COSV53978928, COSV99059845; called by muse, mutect2, varscan2
- AGBL5 | c.1260C>G p.I420M | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59935415; called by muse, mutect2, varscan2
- AGGF1 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100461775; called by muse, mutect2, varscan2
- AGPAT4 | c.155G>A p.R52K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100211306; called by muse, mutect2, varscan2
- AKAP13 | c.8309C>T p.S2770F (on ENST00000394518 / NM_007200.5; = p.S2774F on NM_006738.6) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV100773670, COSV100774315; called by muse, mutect2, varscan2
- ALDH9A1 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as rs755173841, COSV100699297, COSV61341344; called by muse, mutect2, varscan2
- ALS2 | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51883563, COSV99969206; called by muse, mutect2, varscan2
- AMPD1 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100815008; called by muse, mutect2, varscan2
- AMY1A | c.1066A>T p.S356C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100915787; called by mutect2, varscan2
- ANKRD11 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.042); catalogued as COSV99969116; called by muse, mutect2, varscan2
- ANKRD12 | c.2605G>C p.E869Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as COSV100041185; called by muse, mutect2, varscan2
- ANKRD17 | c.3157C>G p.Q1053E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.027); catalogued as COSV100429019; called by muse, mutect2
- ANKRD30A | c.3520G>A p.E1174K (on ENST00000611781; = p.E1118K on NM_052997.2) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100653395; called by muse, mutect2, varscan2
- ANO6 | c.2005G>C p.E669Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100263025; called by muse, mutect2, varscan2
- APLNR | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57242856, COSV99951412; called by muse, mutect2, varscan2
- ARHGAP12 | c.2188C>G p.L730V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100260557; called by muse, mutect2, varscan2
- ARHGEF18 | c.1518G>C p.E506D (on ENST00000359920 / NM_001130955.2; = p.E402D on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV100149444; called by muse, mutect2
- ARMCX1 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100863186; called by muse, mutect2, varscan2
- ASAP2 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.98); catalogued as COSV99856105; called by muse, mutect2, varscan2
- ASH2L | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV99166966; called by muse, mutect2, varscan2
- ASTN1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as COSV99921374; called by muse, varscan2
- ATP2B1 | c.3176C>T p.S1059L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.154); catalogued as COSV99665815; called by muse, mutect2
- BBS4 | c.1042C>G p.L348V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99166425; called by muse, mutect2, varscan2
- BEX3 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV55421027; called by muse, mutect2, varscan2
- BGN | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100525175, COSV59035987; called by muse, mutect2
- BRIP1 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369631413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.3784C>T p.Q1262* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as COSV99608208; called by muse, mutect2, varscan2
- BTAF1 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99795248; called by muse, mutect2, varscan2
- C1orf112 | c.90G>A p.M30I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV99609694; called by muse, mutect2, varscan2
- C1orf174 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV100851760; called by muse, mutect2, varscan2
- C6orf89 | c.197C>A p.A66E (on ENST00000373685; = p.A73E on NM_152734.4) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs779924954, COSV100769717; called by muse, mutect2, varscan2
- CCDC15 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100776964; called by muse, mutect2, varscan2
- CCDC9B | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as rs984275947, COSV101233511; called by muse, mutect2, varscan2
- CCIN | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs768784722, COSV100631805; called by muse, mutect2, varscan2
- CCNB3 | c.2266C>T p.H756Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV99328907; called by muse, mutect2, varscan2
- CCNJ | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV56443655; called by muse, mutect2, varscan2
- CD177 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100945936; called by muse, mutect2, varscan2
- CD200R1 | c.280G>A p.E94K (on ENST00000471858 / NM_170780.3; = p.E117K on NM_138806.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99867142; called by muse, mutect2
- CD8B | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs753422558, COSV100514475; called by muse, mutect2, varscan2
- CDCP1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV99944012; called by muse, mutect2, varscan2
- CDHR2 | c.1013G>T p.W338L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.053); catalogued as COSV99991492; called by muse, mutect2, varscan2
- CDKL4 | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV101115238, COSV66508878; called by muse, mutect2, varscan2
- CEACAM20 | c.398C>G p.S133* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as rs1038653090, COSV100386863; called by muse, mutect2, varscan2
- CEACAM8 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54990974, COSV99747576; called by muse, mutect2, varscan2
- CENPO | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV99578961; called by muse, mutect2, varscan2
- CGN | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.994); catalogued as COSV99642240; called by muse, mutect2, varscan2
- CHD7 | c.7343C>G p.S2448* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV101418208; called by muse, mutect2, varscan2
- CLEC4M | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV50218710; called by muse, mutect2
- CLOCK | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV100011740; called by mutect2, varscan2
- CLTA | c.746G>T p.*249Lext*39 (on ENST00000242285 / NM_007096.4; = p.*219Lext*39 on NM_001833.4 and 2 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99643592; called by muse, mutect2, varscan2
- CMYA5 | c.5334G>C p.L1778F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV101484020; called by muse, mutect2, varscan2
- COL4A1 | c.1909G>T p.E637* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV101011102; called by muse, mutect2, varscan2
- COL4A4 | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV61629456; called by muse, mutect2, varscan2
- CPEB1 | c.1755C>G p.F585L (on ENST00000617958; = p.F520L on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99917639; called by muse, mutect2, varscan2
- CPXM1 | c.966C>G p.I322M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV101013719; called by muse, mutect2, varscan2
- CSF1R | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1315261761, COSV53835903; called by muse, mutect2, varscan2
- CTTNBP2 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as rs1319157563, COSV99353762; called by muse, mutect2, varscan2
- CWC22 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as COSV99844213; called by muse, mutect2, varscan2
- CYBB | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV101059742, COSV101059782; called by muse, mutect2, varscan2
- CYTH4 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99957889; called by muse, mutect2, varscan2
- DAZAP1 | c.417C>T p.V139= | Splice Region (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99245168; called by muse, mutect2, varscan2
- DCAF15 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99586802, COSV99586973; called by muse, mutect2, varscan2
- DCAF16 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.026); catalogued as COSV66384316; called by mutect2, varscan2
- DCLK2 | c.1163C>G p.S388* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV99651912; called by muse, mutect2, varscan2
- DEF6 | c.1861C>G p.Q621E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as rs144407329, COSV100359273, COSV100359380; called by muse, mutect2, varscan2
- DHX35 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284772940, COSV99326748; called by muse, varscan2
- DIAPH1 | c.2826C>G p.F942L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99526429; called by muse, mutect2, varscan2
- DMXL2 | c.3005C>T p.S1002F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99196285; called by muse, mutect2, varscan2
- DNAJB14 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs1321258211, COSV100508435; called by muse, mutect2, varscan2
- DNMT1 | c.1126G>C p.D376H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100532372; called by muse, mutect2, varscan2
- DSG2 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as CM1312996, COSV99853080; called by mutect2, varscan2
- EFR3A | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99602894; called by muse, mutect2
- EFTUD2 | c.2302C>G p.Q768E | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99493931, COSV99494053; called by muse, mutect2, varscan2
- EIF2B1 | c.102G>C p.L34F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV57459800; called by muse, mutect2, varscan2
- ELP2 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100626804; called by muse, mutect2, varscan2
- EMC1 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100617471; called by muse, mutect2, varscan2
- EPB41L4B | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs267602080, COSV65797002; called by muse, mutect2, varscan2
- ERCC6L | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100559090, COSV57819702; called by muse, mutect2, varscan2
- ESPL1 | c.4003C>T p.Q1335* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as COSV57759381, COSV99229234; called by muse, mutect2
- ETNPPL | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99625198; called by muse, mutect2, varscan2
- EYS | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100676333; called by muse, mutect2, varscan2
- FAM13A | c.2874G>A p.M958I | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV99983471; called by muse, mutect2, varscan2
- FAM171A1 | c.842G>A p.W281* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100968228; called by muse, mutect2, varscan2
- FAM47B | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.929); catalogued as COSV100264282, COSV61452799; called by muse, mutect2, varscan2
- FANCM | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs757274359, COSV99950966; called by muse, mutect2, varscan2
- FAT1 | c.12283G>A p.D4095N | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.99); catalogued as COSV101499309, COSV71676158; called by muse, mutect2, varscan2
- FAT1 | c.6098C>G p.S2033* | Nonsense Mutation (SNP) | VAF 29/41 reads (71%) | catalogued as COSV71673625; called by muse, mutect2, varscan2
- FAT4 | c.14275C>T p.Q4759* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100628401; called by muse, mutect2, varscan2
- FBXL7 | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV100309635; called by muse, mutect2
- FBXW7 | c.881C>A p.S294* (on ENST00000281708 / NM_001349798.2; = p.S214* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99656421; called by muse, mutect2, varscan2
- FCRLB | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100396165; called by muse, mutect2, varscan2
- FETUB | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV99408974; called by muse, mutect2, varscan2
- FKBP7 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99247566; called by muse, mutect2, varscan2
- FLG | c.6866G>C p.R2289T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs759013786, COSV100911506; called by muse, mutect2, varscan2
- FLG | c.6572G>A p.R2191K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.191); catalogued as COSV100910913, COSV100911507; called by muse, mutect2, varscan2
- FLG2 | c.2695C>A p.Q899K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV101165814; called by muse, mutect2, varscan2
- FMN2 | c.2671C>G p.L891V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.245); catalogued as COSV100144729, COSV60420070; called by muse, mutect2, varscan2
- FMNL2 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99979495; called by muse, mutect2, varscan2
- FOCAD | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100620338; called by muse, mutect2, varscan2
- FSD2 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV100575113; called by muse, mutect2, varscan2
- GALNT14 | c.297G>A p.L99= | Splice Region (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100204538; called by muse, mutect2
- GDAP2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.864); catalogued as COSV101031960; called by muse, mutect2, varscan2
- GEM | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749374110, COSV52596809; called by muse, mutect2, varscan2
- GOLGA5 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99370881; called by muse, mutect2, varscan2
- GPRASP2 | c.644G>A p.R215K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100176706, COSV59992302; called by muse, mutect2, varscan2
- GRAMD1A | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as rs1323825707, COSV100526132; called by muse, mutect2, varscan2
- GRIN2B | c.2673G>T p.M891I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); catalogued as COSV101663010; called by muse, mutect2
- GRIP1 | c.1405G>C p.E469Q (on ENST00000359742 / NM_001379345.1; = p.E417Q on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99669203; called by muse, mutect2, varscan2
- GUCY2F | c.1508C>A p.P503H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99484889; called by muse, mutect2, varscan2
- HCN2 | c.793A>G p.T265A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99241732; called by muse, mutect2, varscan2
- HDAC8 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101003289, COSV101003293; called by muse, mutect2, varscan2
- HERC2 | c.10402G>A p.E3468K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV99873134; called by muse, mutect2, varscan2
- HGF | c.2052G>C p.M684I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV55953559, COSV99736713; called by muse, mutect2, varscan2
- HMCN1 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.239); catalogued as COSV99628294; called by muse, mutect2, varscan2
- HSP90AB1 | c.52C>G p.Q18E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as COSV62334504, COSV62336891; called by muse, mutect2, varscan2
- HSPA8 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.672); catalogued as COSV99914358; called by muse, mutect2, varscan2
- IFI44 | c.934G>C p.D312H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV100877317; called by muse, mutect2, varscan2
- IGHV3-15 | c.158T>A p.M53K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs782411246; called by muse, mutect2, varscan2
- IHO1 | c.1546C>G p.L516V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV56507655, COSV99606080; called by muse, mutect2
- IPO11 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV100320680; called by muse, mutect2, varscan2
- IQCN | c.1684C>G p.Q562E | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.154); catalogued as COSV101148605; called by muse, mutect2, varscan2
- ITGB1 | c.2216G>C p.G739A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100171585; called by muse, mutect2, varscan2
- ITGB1 | c.1867C>G p.P623A | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.101); catalogued as COSV100171588; called by muse, mutect2, varscan2
- KIAA1210 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as rs1223301206, COSV68177412; called by muse, mutect2, varscan2
- KIAA1549L | c.5044G>A p.A1682T (on ENST00000321505; = p.A1979T on NM_012194.3) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV58595367; called by muse, mutect2, varscan2
- KIAA1841 | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99693601; called by muse, mutect2, varscan2
- KIF27 | c.1954G>T p.E652* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99926929; called by muse, mutect2
- KIF5A | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99672871; called by muse, mutect2, varscan2
- KMT2D | c.16159C>T p.Q5387* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99980828; called by muse, mutect2, varscan2
- KMT2D | c.4303C>T p.Q1435* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV56450220, COSV99980831; called by muse, mutect2, varscan2
- KRT75 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as rs200222543, COSV52873125, COSV52873510, COSV99359378; called by muse, mutect2
- LAMC2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99917377; called by muse, mutect2, varscan2
- LHX8 | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV53958762, COSV99633158; called by muse, mutect2, varscan2
- LIMK1 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1277922092, COSV60282038; called by muse, mutect2
- LIN54 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.334); catalogued as COSV100464514; called by muse, mutect2, varscan2
- LRCH2 | c.1120C>G p.Q374E | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.931); catalogued as COSV57746395; called by muse, mutect2
- LRIT3 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100016067; called by muse, mutect2, varscan2
- LRRCC1 | c.1537C>T p.Q513* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as rs778399732, COSV64485335; called by muse, mutect2, varscan2
- LRRIQ1 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as COSV101280119; called by muse, mutect2, varscan2
- LZIC | c.102-1G>C p.X34_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as COSV101021317; called by muse, mutect2, varscan2
- MAGEB4 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.261); catalogued as rs867247380, COSV100854677; called by muse, mutect2, varscan2
- MAOA | c.1018A>C p.T340P | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100108740; called by muse, mutect2, varscan2
- MAP3K13 | c.1889C>G p.S630C | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.171); catalogued as COSV99407016; called by muse, mutect2
- MAP3K15 | c.2482T>A p.Y828N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100134614; called by muse, mutect2
- MAP3K15 | c.2480G>A p.G827E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV58838414; called by muse, mutect2
- MAP4K3 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99810307; called by muse, mutect2, varscan2
- MAP7D3 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs761764817, COSV100286249; called by muse, mutect2, varscan2
- MCM4 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV100031476, COSV50622533; called by muse, mutect2
- MED13 | c.3805G>A p.D1269N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV101180988; called by muse, mutect2, varscan2
- METTL23 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.583); catalogued as COSV100373029; called by muse, mutect2, varscan2
- MON2 | c.2754-1G>C p.X918_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99742377; called by muse, mutect2, varscan2
- MSH3 | c.1990C>T p.Q664* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99433393; called by muse, mutect2, varscan2
- MUC16 | c.19233C>G p.I6411M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.266); catalogued as COSV101199620; called by mutect2, varscan2
- MUC7 | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.206); catalogued as COSV100512280; called by muse, mutect2, varscan2
- MUCL1 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs539263727, COSV58193061; called by mutect2, varscan2
- NAXD | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as rs1321987658, COSV100010438; called by muse, mutect2, varscan2
- NCOA5 | c.416G>C p.R139T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV99275502; called by muse, mutect2, varscan2
- NDC1 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99323564; called by muse, mutect2, varscan2
- NDEL1 | c.973C>G p.P325A | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100232936; called by muse, mutect2, varscan2
- NDP | c.170C>G p.S57* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as CM920498, COSV100955732; called by muse, mutect2, varscan2
- NEB | c.7186G>A p.D2396N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs867897450, COSV51078603; called by muse, mutect2, varscan2
- NEK1 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101455669; called by muse, mutect2, varscan2
- NKRF | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.536); catalogued as COSV100441595; called by muse, mutect2, varscan2
- NMU | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99946386; called by muse, mutect2, varscan2
- NRK | c.1861C>G p.Q621E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs749864252, COSV99687522, COSV99688747; called by muse, mutect2, varscan2
- NSUN2 | c.1520C>T p.S507L | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV99243127; called by muse, mutect2
- NUP153 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as rs1447377557, COSV100020201; called by muse, mutect2, varscan2
- NXF1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.156); catalogued as COSV99586005; called by muse, mutect2, varscan2
- NXF3 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV101221934; called by muse, mutect2, varscan2
- OR2B11 | c.920G>C p.R307T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV100275874; called by muse, mutect2, varscan2
- OR51E2 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.211); catalogued as COSV101211336; called by muse, mutect2, varscan2
- OR52E6 | c.153C>G p.I51M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100259300, COSV61432903; called by muse, mutect2, varscan2
- OR52J3 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66746307, COSV66746315; called by muse, mutect2
- OR5K2 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs1451705717, COSV101415963, COSV101415972; called by muse, mutect2, varscan2
- OR5T2 | c.198C>G p.F66L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100506915; called by muse, mutect2, varscan2
- OR8H2 | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100542282; called by muse, mutect2, varscan2
- OTOL1 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs770828019, COSV60007332; called by muse, mutect2, varscan2
- PAPPA2 | c.4323G>T p.Q1441H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV100867968, COSV62808287; called by muse, mutect2, varscan2
- PARD3 | c.3753G>C p.Q1251H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV61048581, COSV61061464; called by muse, mutect2, varscan2
- PARP14 | c.3128G>A p.R1043K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as COSV101506267; called by muse, mutect2, varscan2
- PARP8 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV99891097; called by muse, mutect2, varscan2
- PATJ | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100334008; called by muse, mutect2
- PCDHA11 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.033); catalogued as COSV100249957; called by muse, mutect2
- PCNX4 | c.2666G>A p.G889E (on ENST00000406854 / NM_001330177.2; = p.G655E on NM_022495.5) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100470219; called by muse, mutect2, varscan2
- PDE4D | c.1997C>T p.S666F (on ENST00000340635 / NM_001104631.2; = p.S530F on NM_006203.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100401691; called by muse, mutect2, varscan2
- PFN1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.26); catalogued as COSV52590684, COSV99337334; called by muse, mutect2, varscan2
- PHKA1 | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.359); catalogued as COSV100263059; called by muse, mutect2, varscan2
- PIGM | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV100928030, COSV100928057; called by muse, mutect2, varscan2
- PLCB3 | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99657348; called by muse, mutect2, varscan2
- PLXND1 | c.4303G>A p.D1435N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs763865454, COSV100139611; called by mutect2, varscan2
- PLXND1 | c.4198G>A p.E1400K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV100139612; called by mutect2, varscan2
- PRAMEF19 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs879225837; called by muse, varscan2
- PRDM5 | c.1524C>G p.I508M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as COSV53358532, COSV99310433; called by muse, mutect2, varscan2
- PRDX5 | c.480G>A p.E160= | Splice Region (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99134586; called by muse, varscan2
- PRKDC | c.7210C>T p.R2404C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs768108353, COSV58048939; called by muse, mutect2
- PRKDC | c.5335C>T p.Q1779* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100040195, COSV58059841; called by muse, mutect2, varscan2
- PRPF18 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); catalogued as rs372960380; called by muse, mutect2, varscan2
- PRRC2A | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.824); catalogued as rs1461963315, COSV100784568; called by muse, mutect2, varscan2
- PRRC2B | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780688754, COSV61938904; called by muse, mutect2, varscan2
- PSD2 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs773205125, COSV51199770; called by muse, mutect2, varscan2
- PSG5 | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.122); catalogued as COSV100742766; called by muse, mutect2, varscan2
- PSG8 | c.83G>A p.W28* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100126139; called by muse, varscan2
- PTPN13 | c.5012C>G p.S1671* (on ENST00000411767 / NM_080683.3; = p.S1652* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as rs1441290962, COSV100364612; called by muse, varscan2
- PTPN13 | c.5063C>T p.S1688L (on ENST00000411767 / NM_080683.3; = p.S1669L on NM_006264.3) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.075); catalogued as COSV100364614; called by muse, varscan2
- PUM1 | c.3417C>G p.I1139M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.35); catalogued as COSV99927905; called by muse, mutect2, varscan2
- PXYLP1 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.862); catalogued as COSV99649405; called by muse, mutect2
- PYM1 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.174); catalogued as COSV100212645; called by muse, mutect2, varscan2
- RAB33A | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99924532; called by muse, mutect2, varscan2
- RAB7A | c.103A>C p.N35H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV99414044; called by muse, mutect2, varscan2
- RABEPK | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV99413360; called by muse, mutect2, varscan2
- RAD9B | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs753692522, COSV63779347; called by mutect2, varscan2
- RB1CC1 | c.1949C>G p.S650C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99212211; called by muse, mutect2, varscan2
- RFPL2 | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.223); catalogued as COSV99964195; called by mutect2, varscan2
- RIMS1 | c.3262T>C p.C1088R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1350481528, COSV99326192; called by muse, mutect2, varscan2
- RNF146 | c.824C>T p.S275L (on ENST00000368314 / NM_001242850.2; = p.S274L on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.288); catalogued as COSV100541717; called by muse, mutect2, varscan2
- ROBO1 | c.1264G>C p.D422H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101458646; called by muse, mutect2, varscan2
- RSRC2 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.133); catalogued as COSV100063515; called by muse, mutect2, varscan2
- SALL1 | c.532C>G p.Q178E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99173526; called by muse, varscan2
- SARDH | c.1326C>T p.I442= | Splice Region (SNP) | VAF 17/36 reads (47%) | catalogued as COSV64104412; called by muse, mutect2, varscan2
- SASH1 | c.2872G>A p.E958K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.156); catalogued as rs751020609; called by muse, mutect2
- SATB2 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.879); catalogued as COSV99611135; called by muse, mutect2, varscan2
- SDHA | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.354); catalogued as COSV53765465, COSV99371566; called by muse, mutect2
- SEC14L3 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99307122; called by muse, mutect2, varscan2
- SEC23IP | c.2078G>C p.R693T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100956851; called by muse, mutect2, varscan2
- SEPTIN3 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs780575909, COSV99351853; called by muse, mutect2, varscan2
- SERPINA3 | c.1242G>C p.M414I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV101261678; called by muse, mutect2, varscan2
- SH3GL1 | c.115-1G>A p.X39_splice | Splice Site (SNP) | VAF 16/50 reads (32%) | catalogued as rs768517510, COSV99522559; called by muse, varscan2
- SHANK2 | c.4180C>T p.P1394S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99573588; called by muse, mutect2, varscan2
- SLC12A1 | c.2937C>G p.I979M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV101118600; called by muse, mutect2, varscan2
- SLC35D2 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99480814; called by muse, mutect2, varscan2
- SLC6A3 | c.399G>C p.K133N | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as CD108195, COSV99548205; called by muse, mutect2
- SOHLH2 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV65901740; called by muse, mutect2
- SPAG17 | c.5078G>A p.R1693H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs761981749, COSV60468731; called by muse, mutect2, varscan2
- SPAG9 | c.1998G>A p.M666I (on ENST00000262013 / NM_001130528.3; = p.M652I on NM_003971.6) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100005049; called by muse, mutect2, varscan2
- SPOPL | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV104381323, COSV99699444; called by muse, mutect2, varscan2
- SPTBN1 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs752488873, COSV61692850; called by muse, mutect2, varscan2
- SPTBN2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100019116; called by muse, mutect2, varscan2
- SRCAP | c.7453C>A p.P2485T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV99349985; called by muse, mutect2, varscan2
- SRCAP | c.8773C>T p.H2925Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.255); catalogued as COSV99349986; called by muse, mutect2, varscan2
- SRGAP1 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.733); catalogued as COSV100754572, COSV61895205; called by muse, mutect2, varscan2
- SRRM2 | c.6564C>G p.I2188M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV99241442; called by muse, mutect2, varscan2
- SRSF2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV57969999; called by muse, varscan2
- SRSF2 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs1326283685, COSV57969995, COSV57975979; called by muse, varscan2
- SUGP2 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100432342, COSV58258800; called by muse, mutect2, varscan2
- SULT6B1 | c.892G>A p.E298K (on ENST00000535679 / NM_001367551.1; = p.E260K on NM_001032377.2) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs772460482, COSV99573046; called by muse, mutect2, varscan2
- SULT6B1 | c.797G>C p.W266S (on ENST00000535679 / NM_001367551.1; = p.W228S on NM_001032377.2) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99573150; called by muse, mutect2, varscan2
- SYDE2 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99320436; called by muse, mutect2, varscan2
- TADA1 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as rs1357827519, COSV100902311; called by muse, mutect2
- TAF4B | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs751006210, COSV99300124; called by muse, mutect2, varscan2
- TEX10 | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100887719; called by muse, mutect2, varscan2
- TEX55 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.236); catalogued as rs755399352, COSV55210681; called by muse, mutect2, varscan2
- THAP7 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs755408769, COSV53145783, COSV99301459; called by muse, mutect2, varscan2
- THOC2 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV99833168; called by muse, mutect2, varscan2
- TIAL1 | c.704G>C p.R235T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100958350; called by muse, mutect2, varscan2
- TIAM2 | c.5044C>T p.Q1682* (on ENST00000529824; = p.Q1653* on NM_012454.3) | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99265394; called by muse, mutect2, varscan2
- TLR10 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100457598; called by muse, mutect2, varscan2
- TMEM215 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV100713169; called by muse, mutect2, varscan2
- TMEM266 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101189607; called by muse, mutect2, varscan2
- TMEM51 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV101051518; called by muse, mutect2
- TMTC3 | c.2073G>A p.M691I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99898293; called by muse, mutect2, varscan2
- TOMM34 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV100861887, COSV65689264; called by mutect2, varscan2
- TPTE2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.01); catalogued as rs1566068676, COSV99690212; called by muse, mutect2, varscan2
- TRPS1 | c.3149G>T p.G1050V (on ENST00000220888 / NM_001330599.2; = p.G1063V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.942); catalogued as COSV55229155, COSV99630260; called by muse, mutect2, varscan2
- TRPV6 | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV63893179; called by muse, mutect2, varscan2
- TUBGCP2 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.698); catalogued as COSV53306655, COSV99427588; called by muse, mutect2, varscan2
- TULP4 | c.3862G>C p.E1288Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV100893429; called by muse, mutect2
- UBN1 | c.3364C>A p.Q1122K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs1410571610, COSV99277892; called by muse, mutect2, varscan2
- UBR5 | c.4999C>G p.Q1667E | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.68); catalogued as COSV99640668; called by muse, mutect2, varscan2
- UBR5 | c.2900C>T p.S967L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); catalogued as COSV99640671; called by muse, mutect2, varscan2
- UMOD | c.935G>A p.R312K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV100208302; called by muse, mutect2
- UNC13B | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as COSV65933932; called by muse, mutect2, varscan2
- USP13 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55865528; called by muse, mutect2, varscan2
- UTS2 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99276760; called by muse, mutect2, varscan2
- VRK2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs1213411092, COSV100417819; called by muse, mutect2, varscan2
- VWC2 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100514158; called by muse, mutect2, varscan2
- WASF1 | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99661162, COSV99661508; called by muse, mutect2, varscan2
- WDFY3 | c.2053C>G p.L685V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV99883231; called by muse, mutect2, varscan2
- YARS2 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV100256383; called by muse, mutect2, varscan2
- YLPM1 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV99459426; called by muse, mutect2, varscan2
- YOD1 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100262997; called by muse, varscan2
- ZBTB37 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100875224; called by muse, mutect2, varscan2
- ZBTB43 | c.1173G>C p.M391I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100991355; called by muse, mutect2, varscan2
- ZC3H13 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99668017; called by muse, mutect2, varscan2
- ZFP91 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100284470, COSV60162226; called by muse, mutect2, varscan2
- ZNF330 | c.472C>G p.Q158E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1362235546, COSV99522474; called by muse, mutect2, varscan2
- ZNF407 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99995522; called by muse, mutect2, varscan2
- ZNF585A | c.1239G>A p.M413I (on ENST00000292841 / NM_001288800.2; = p.M358I on NM_152655.3) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV99493052; called by muse, mutect2, varscan2
- ZNF606 | c.1817G>T p.R606I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV58706731; called by muse, mutect2, varscan2
- ZNF638 | c.2538G>T p.K846N | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100038614; called by muse, mutect2, varscan2
- ZNF791 | c.1391G>C p.G464A | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100589076; called by muse, mutect2, varscan2
- ZNF91 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV100322615; called by muse, mutect2, varscan2
- ZNF91 | c.1760C>G p.S587* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV56087503; called by muse, mutect2, varscan2
- ZNF93 | c.757G>C p.G253R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.633); catalogued as COSV100652263, COSV100652448; called by muse, mutect2, varscan2
- ZNF99 | c.1364G>A p.C455Y | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159759371, COSV101233812; called by muse, mutect2, varscan2
- ZNFX1 | c.1271C>G p.S424* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100870819; called by muse, mutect2, varscan2
- ZSWIM3 | c.1742G>A p.C581Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV99666478; called by muse, mutect2, varscan2
- ZSWIM8 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV101289879; called by muse, mutect2, varscan2
- ZSWIM8 | c.684G>C p.Q228H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.986); catalogued as COSV101289880; called by muse, mutect2
- ZSWIM8 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101289881; called by muse, mutect2, varscan2
- GPR160 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2
- IRS1 | c.1648_1650del p.E550del | In Frame Del (DEL) | VAF 7/34 reads (21%) | called by pindel, varscan2
- LILRB3 | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, varscan2
- LILRB3 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.22); called by muse, varscan2
- NLRC4 | c.2048del p.I683Nfs*12 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- SNAP23 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SPDYE5 | c.213G>C p.K71N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ADPRM | c.741C>T p.D247= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs368408429, COSV59379608; called by muse, mutect2, varscan2
- AGTPBP1 | c.801C>G p.L267= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100429660; called by muse, mutect2, varscan2
- ALCAM | c.981C>T p.I327= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100064684; called by muse, mutect2
- ARL16 | c.216C>A p.I72= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100230449, COSV61267555; called by muse, mutect2, varscan2
- ARRB1 | c.861C>T p.L287= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs373519168; called by muse, mutect2, varscan2
- ASCC3 | c.5748C>G p.V1916= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV100976427; called by muse, mutect2, varscan2
- ASTN2 | c.3196C>T p.L1066= (on ENST00000313400 / NM_001365069.1; = p.L1015= on NM_014010.5) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99940698; called by muse, mutect2, varscan2
- BCLAF3 | c.2004G>A p.Q668= (on ENST00000379682 / NM_001367774.1; = p.Q639= on NM_198279.3) | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs1345005758, COSV100503284; called by muse, mutect2, varscan2
- BRWD3 | c.4713C>T p.I1571= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100955960, COSV64746123; called by muse, mutect2, varscan2
- CAPN3 | c.657G>A p.L219= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs936809088, COSV100532904; called by muse, mutect2, varscan2
- CHD7 | c.3330G>A p.L1110= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV101418206; called by muse, mutect2, varscan2
- CNTN6 | c.2628T>C p.F876= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100610571; called by muse, mutect2, varscan2
- COPS7A | c.225C>T p.Y75= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs914116973, COSV99976439; called by muse, mutect2, varscan2
- CPPED1 | c.105C>T p.F35= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99903092; called by muse, mutect2, varscan2
- CRISPLD2 | c.1152G>T p.V384= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs1280810312, COSV99295603; called by muse, mutect2, varscan2
- CSMD1 | c.10527C>G p.L3509= (on ENST00000520002; = p.L3508= on NM_033225.6) | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100146999, COSV100149322; called by muse, mutect2
- DCTN4 | c.69G>A p.P23= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV69783224; called by muse, mutect2, varscan2
- DENND2B | c.3009G>A p.K1003= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100567418, COSV58206366; called by muse, varscan2
- DNAH2 | c.4755G>A p.G1585= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV101209238, COSV66716078; called by muse, mutect2, varscan2
- DNAH2 | c.6588C>T p.I2196= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs754746688, COSV66717133; called by muse, mutect2
- EHHADH | c.663G>C p.R221= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99213168; called by muse, mutect2, varscan2
- EXD1 | c.933G>A p.Q311= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100153594; called by muse, mutect2, varscan2
- FAM209B | c.102G>A p.G34= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100990953; called by muse, mutect2, varscan2
- FAT1 | c.10005C>T p.F3335= | Silent (SNP) | VAF 42/71 reads (59%) | catalogued as COSV101499310; called by muse, mutect2, varscan2
- FAT1 | c.5040C>T p.V1680= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as COSV101499311; called by muse, mutect2, varscan2
- FBXO22 | c.1065C>T p.F355= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1015124403, COSV100380542; called by muse, mutect2, varscan2
- FCHO1 | c.69G>A p.V23= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99406060; called by muse, mutect2, varscan2
- FEZ1 | c.168C>T p.F56= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV99630555; called by muse, mutect2, varscan2
- FGFR1 | c.1047C>T p.L349= (on ENST00000447712 / NM_023110.3; = p.L347= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV58334492; called by muse, mutect2, varscan2
- FGFR2 | c.2148G>A p.L716= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100336110; called by muse, mutect2, varscan2
- FLVCR2 | c.1473C>T p.L491= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99471248; called by muse, mutect2, varscan2
- FRMPD1 | c.3438G>A p.Q1146= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100899544; called by muse, mutect2, varscan2
- FRYL | c.8073C>T p.V2691= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV51961619; called by muse, mutect2, varscan2
- FRYL | c.4224C>T p.I1408= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99976711; called by muse, mutect2, varscan2
- GCC2 | c.3336G>A p.Q1112= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs112143014, COSV100565411; called by muse, mutect2, varscan2
- GDPD5 | c.588C>G p.L196= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100409273; called by muse, mutect2, varscan2
- GGTLC1 | c.294C>T p.F98= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as COSV53847135; called by muse, mutect2, varscan2
- GINM1 | c.909C>T p.D303= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs766884857, COSV59503444; called by muse, mutect2, varscan2
- GPR156 | c.1278G>A p.S426= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs200523370; called by muse, mutect2, varscan2
- GRIP1 | c.2526G>A p.Q842= (on ENST00000359742 / NM_001379345.1; = p.Q790= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV54049125; called by muse, mutect2, varscan2
- GRM1 | c.1680C>T p.F560= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99265785; called by muse, mutect2, varscan2
- GSPT2 | c.1728G>A p.V576= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100468124; called by muse, mutect2, varscan2
- HLA-A | c.675G>A p.L225= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100954382, COSV65140303, COSV65141497; called by muse, mutect2, varscan2
- HSPA9 | c.1050A>G p.Q350= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs1480795712, COSV99785423; called by muse, mutect2, varscan2
- IMPG2 | c.315G>A p.V105= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99515441; called by muse, mutect2, varscan2
- INO80E | c.66C>G p.L22= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV99662994; called by muse, mutect2, varscan2
- KAZN | c.468G>A p.V156= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs757830663, COSV100747790; called by muse, varscan2
- KCNH4 | c.1869C>T p.I623= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs373847382, COSV99237085; called by muse, mutect2, varscan2
- KCNS2 | c.729G>A p.V243= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99751087; called by muse, mutect2, varscan2
- KLHL4 | c.600C>T p.L200= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100909487, COSV100910074; called by muse, mutect2, varscan2
- LAYN | c.873C>G p.V291= (on ENST00000375615 / NM_001258390.1; = p.V283= on NM_178834.5) | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV100986208; called by muse, mutect2, varscan2
- LCE2A | c.320G>A p.*107= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100909149; called by muse, mutect2, varscan2
- LHFPL1 | c.111G>A p.Q37= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100914449, COSV64333330; called by muse, mutect2, varscan2
- LPO | c.1725C>G p.L575= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV51858647, COSV99228721; called by muse, mutect2, varscan2
- MMS22L | c.1173C>A p.I391= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs1472566568, COSV99246353; called by muse, mutect2, varscan2
- MPDZ | c.4308G>A p.V1436= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100056661; called by muse, mutect2, varscan2
- MUC16 | c.37233G>A p.R12411= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV67454174; called by muse, mutect2, varscan2
- MYO7B | c.1899C>T p.F633= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV67344126; called by muse, mutect2, varscan2
- NBEA | c.7545G>A p.L2515= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100079410; called by muse, mutect2, varscan2
- NEK1 | c.2988G>A p.L996= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV101455668; called by muse, mutect2, varscan2
- NLRP3 | c.1224C>T p.F408= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100275872; called by muse, mutect2, varscan2
- NME9 | c.256C>T p.L86= (on ENST00000333911 / NM_001349024.2; = p.L64= on NM_178130.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV58619224, COSV58621943; called by muse, mutect2, varscan2
- NOX3 | c.1482C>T p.D494= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs764249682, COSV50161000; called by muse, mutect2, varscan2
- NPFFR1 | c.153G>A p.A51= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs757892436, COSV53332662, COSV53335240; called by muse, mutect2, varscan2
- NUP205 | c.385T>C p.L129= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99606924; called by muse, mutect2, varscan2
- OAS3 | c.2391C>T p.I797= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99966234; called by muse, mutect2, varscan2
- OCRL | c.1344G>A p.L448= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100843421, COSV63981021; called by muse, mutect2, varscan2
- OR2AK2 | c.117G>A p.L39= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100823534, COSV63557057; called by muse, mutect2, varscan2
- OR2M5 | c.771C>T p.F257= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV63545786, COSV63545832; called by muse, varscan2
- OR4F15 | c.741C>T p.V247= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100173880; called by muse, mutect2, varscan2
- OR51V1 | c.460A>C p.R154= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100343354; called by muse, mutect2, varscan2
- OR5P3 | c.663C>T p.I221= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100103121; called by muse, mutect2, varscan2
- PCDH9 | c.441C>T p.I147= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100120189; called by muse, mutect2, varscan2
- PLAU | c.642C>T p.I214= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV65640895; called by muse, mutect2
- PLEKHA7 | c.2151G>A p.E717= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100850228, COSV63044086; called by muse, mutect2, varscan2
- PM20D1 | c.519G>C p.L173= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1001518907, COSV100900176, COSV65648739; called by muse, mutect2, varscan2
- PPARGC1A | c.165C>G p.L55= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99337765; called by muse, mutect2, varscan2
- PPP1R12A | c.2481G>A p.E827= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99700261; called by muse, mutect2, varscan2
- PREX1 | c.3585C>T p.S1195= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs769369609, COSV64254508; called by muse, varscan2
- PTPRK | c.1728C>T p.V576= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs756983574, COSV100950903; called by muse, mutect2, varscan2
- PVRIG | c.549C>A p.L183= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99443812; called by muse, mutect2
- R3HDML | c.726C>T p.F242= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99407121; called by muse, mutect2, varscan2
- RAB8A | c.60G>T p.G20= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as rs761180426, COSV99959764; called by muse, mutect2, varscan2
- RFPL1 | c.615G>C p.G205= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100585740; called by muse, mutect2, varscan2
- RTL5 | c.213C>T p.F71= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs774040323, COSV65452441, COSV65455533; called by muse, mutect2, varscan2
- RYR3 | c.9945G>A p.V3315= (on ENST00000389232; = p.V3316= on NM_001036.6) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV101212610; called by muse, mutect2, varscan2
- SARDH | c.1041C>T p.F347= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs757307357, COSV100897852; called by muse, mutect2, varscan2
- SCD | c.120C>G p.L40= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100948879; called by muse, mutect2, varscan2
- SCNN1G | c.1137G>T p.V379= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV55598404; called by muse, mutect2, varscan2
- SH2D3C | c.144C>T p.D48= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100136828; called by muse, mutect2, varscan2
- SIMC1 | c.2212C>T p.L738= (on ENST00000443967 / NM_001308196.1; = p.L323= on NM_198567.5) | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100231085; called by muse, mutect2, varscan2
- SIPA1L2 | c.2091G>T p.L697= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV99478033; called by muse, mutect2, varscan2
- SLC2A3 | c.375G>A p.L125= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as COSV99306520; called by muse, mutect2, varscan2
- SLC2A4 | c.942C>T p.F314= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs143529618; called by mutect2, varscan2
- SLC4A1 | c.681G>A p.T227= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs779346506, COSV99293284; called by muse, mutect2, varscan2
- SORT1 | c.1599C>T p.I533= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99860699; called by muse, mutect2, varscan2
- SRPRB | c.505C>T p.L169= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV101524155; called by muse, mutect2, varscan2
- STAG2 | c.2073G>A p.L691= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV99493233; called by muse, mutect2, varscan2
- TAF1 | c.3687G>A p.K1229= (on ENST00000373790 / NM_138923.4; = p.K1250= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV52125410, COSV99335538; called by mutect2, varscan2
- TAOK2 | c.525C>T p.I175= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- TBC1D15 | c.480C>T p.L160= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs902198254, COSV100041713; called by muse, mutect2, varscan2
- TNFRSF10A | c.28C>T p.L10= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV55327270, COSV99646164; called by muse, mutect2
- TPK1 | c.159T>C p.Y53= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1275970944, COSV100765624; called by muse, mutect2, varscan2
- TPP1 | c.1056C>T p.L352= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV54993454; called by muse, mutect2, varscan2
- TUBE1 | c.675G>A p.V225= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100898276; called by muse, mutect2, varscan2
- VAV3 | c.2448G>A p.K816= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV58377681; called by muse, mutect2, varscan2
- WDR33 | c.3924G>A p.R1308= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100205278; called by muse, mutect2
- XK | c.258C>G p.V86= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV101064627; called by muse, mutect2, varscan2
- ZFP91 | c.1371G>A p.L457= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- ZNF287 | c.1803C>T p.F601= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV101209374; called by muse, mutect2, varscan2
- ZNF320 | c.1446A>C p.S482= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV101206857; called by muse, mutect2, varscan2
- ZNF329 | c.636C>T p.F212= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV100798720; called by muse, mutect2
- ZNF709 | c.1875C>T p.F625= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV101172164; called by muse, mutect2, varscan2
- ZNF790 | c.414C>T p.F138= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100764813; called by muse, mutect2, varscan2
- C22orf15 | c.251-23C>A | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- DCHS2 | n.2801T>A | RNA (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100251657; called by muse, mutect2, varscan2
- MAGED1 | c.46-324C>G | Intron (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100431529; called by muse, mutect2, varscan2
- SZT2 | c.*481G>A | 3'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100981265; called by muse, mutect2, varscan2
- TTLL8 | c.938+408G>C | Intron (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99838033, COSV99838284; called by muse, mutect2, varscan2
- TTN | c.34264+827G>C | Intron (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100609989; called by muse, mutect2, varscan2
- ZC3H14 | c.1280-1905G>C | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99192963, COSV99193020; called by muse, mutect2, varscan2
